Somatic mutation profile of tumor specimen 0DRXEB from CCDI case PBCHDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,611 days).
Specimen 0DRXEB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4576a9c-ef8e-494c-968e-20ea50891702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRXER (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bc532c3-727a-41e4-bdf2-56980f6cc1b6

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPT2 | c.340+1G>A p.X114_splice | Splice Site (SNP) | VAF 88/211 reads (42%) | catalogued as CS134111; called by muse, mutect2, varscan2
- DNM2 | c.1082G>C p.R361P | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58959510, COSV58973446; called by muse, mutect2, varscan2
- NLRP2 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 170/358 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs540940476; called by muse, mutect2, varscan2
- PRSS21 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 171/373 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs1222739822; called by muse, mutect2, varscan2
- TOPORS | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 225/415 reads (54%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMT3B | c.198C>T p.Y66= | Silent (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2, varscan2
- THYN1 | c.570C>T p.G190= | Silent (SNP) | VAF 132/479 reads (28%) | called by muse, mutect2, varscan2
